Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A933, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A933-01A (Primary Tumor).

[page 1 of 4]
Patient Name

MRN:

DOB:

Gender:

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: mediastinal tumour thymoma - stitch marks superior RIGHT pole of thymus
2. LUNG: portion LLL.
3. LUNG: portion of lingula

ICD-O-3

Thymus, Carcinoma NOS
8586/3

Date: Thymus
CB79
9/24/14

DIAGNOSIS

1. Thymus, resection:
- a) Consistent with thymic carcinoma, non-keratinizing squamous cell type, with:
- i) Greatest tumor dimension = 4.5 cm
- ii) Multifocal invasion of mediastinal adipose tissue
- iii) Invasion into mediastinal pleura, with tumor cells present <0.1 mm from pleural surface (see Comment)
- iii) Thymic resection margins negative for tumor (closest thymic margin 0.4 cm - see Comment)
- b) One of three (1/3) lymph nodes, positive for metastatic carcinoma
- c) Thymic tissue with focal thymic cysts, follicular (lymphoid) hyperplasia, and involutional changes
- 2,3. Lung, wedge resections (left lower lobe, lingula):
- Organizing phase diffuse alveolar damage, with possible progression to fibrosis (see Comment)

SYNOPTIC DATA

Specimen Type:	Not specified
Tumor Site:	Thymus
Tumor Size:	Greatest dimension: 4.5 cm
Histologic Type:	Type C thymoma (thymic carcinoma), epidermoid nonkeratinizing carcinoma/ lymphoepithelioma-like carcinoma
Pathologic Staging:	Stage IIb: Macroscopic capsular

Status: complete

Page: 1 of 4

[page 2 of 4]
Department of Pathology

Patient Name

MRN:	Service:	Collected
DOB:	Visit #:	Resulted:
Gender:	Location:	
	Facility:	

Ordering MD:

invasion

Regional Lymph Nodes:	pN1: Metastasis in anterior
mediastinal lymph nodes	
Distant Metastasis:	Cannot be assessed
Margins:	Margin(s) involved by tumor
	Margin(s): tumor cells present <0.1
mm from mediastinal pleural surface	
Invasion of Pulmonary Parenchyma:	Absent
Pleural Invasion:	Present

COMMENT

1. Sections of the thymic tumor show a partially encapsulated tumor composed of nests and sheets of large, cytologically malignant cells involving thymic tissue, with overt invasion into the surrounding adipose tissue (gross and microscopic). Mitoses are abundant (>30/10 hpf). The tumor focally invades into an apparent pleural surface (presumably mediastinal pleura), where it is present very close to (<0.1 mm) the painted surface of the specimen, with only minimal intervening fibrous tissue. Near the mid-left lobe, tumor cells are noted microscopically 0.4 cm from a thymic resection margin (silver nitrate present on a nest of thymic tissue). One lymph node adjacent to the tumor shows a deposit of metastatic carcinoma. By immunohistochemistry, the tumor cells stain positive for low molecular weight keratin, P63, CD5, and CD117, and focally positive for high molecular weight keratin and CK5/6. The cells are negative for EBV by in situ hybridization. Approximately 20% of the tumor cells stain positive for Mib-1. The tumor is associated with focal aggregates of CD20-positive lymphocytes as well as with occasional infiltrating CD3-positive lymphocytes. CD1a stains dendritic cells as well as lymphocytes within residual thymic tissue, but the tumor-associated lymphocytes are negative for CD1a. The overall findings are in keeping with thymic carcinoma, pT3N1 (mediastinal pleural invasion, anterior mediastinal lymph node metastasis).

2,3. Sections of both lung wedges show similar features, with diffuse interstitial chronic inflammatory infiltrates associated with organizing pneumonia, intra-alveolar edema with proteinaceous material and foamy macrophage accumulation, interstitial fibrosis, and pronounced reactive pneumocyte hyperplasia. Most of the interstitial fibrosis has a recent,

[page 3 of 4]
Department of Pathology

Patient Name

MRN:

DOB:

Gender:F

Service:

Visit #:

Location:

Facility:

Collected

Resulted:

Ordering MD:

organizing appearance, and the underlying parenchymal architecture is, for the most part, preserved. However, occasional small areas with denser fibrosis and possible early architectural remodeling are noted. The small airways show focal chronic inflammation that includes occasional lymphoid aggregates. The blood vessels show reactive changes, but no evidence of active vasculitis. Viral cytopathic effects are not identified. Granulomas and hyaline membranes are not identified. Fungal organisms are not identified in a GMS-stained section. The overall findings are consistent with organizing phase diffuse alveolar damage, possibly with progression to fibrosis. The underlying etiology is not apparent light microscopically. Correlation with clinical findings is needed to exclude potential causes such as infections and drug reactions.

ELECTRONICALLY VERIFIED BY

CLINICAL HISTORY

rule out thymoma

GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "Mediastinal Tumour Thymoma -Stitch Marks Superior Right Pole of Thymus", contains one piece of yellow-tan fibrofatty tissue with a suture designated as superior right pole measuring 11.5 x 8.5 x 2.0 cm. and weighing 58.9 g [fresh] received in 10% buffered formalin. The specimen is painted with silver nitrate. The right lobe measures 8.6 x 4.4 x 1.5 cm and left lobe measures 11.5 x 4.5 x 2.0 cm. Within the mid-left lobe there is a firm tan mass measuring 4.5 x 2.8 x 2.0 cm, the surface of which protrudes from the specimen and appears smooth. On cut sections, the tumor grossly appears to infiltrate the surrounding fat. Four pieces of tumor and three pieces of normal tissue are submitted for tumor bank. Representative sections are submitted as follows:

1A- 1C right lobe from superior to inferior.

1D - 1J Left lobe from superior to inferior (1E - 1I mass)

1L-1R remainder of tumor in toto

2. The specimen is labeled with the patient's identification and as "Portion of LLL".

Resection specimen: Wedge resection.

Measurements: 3.1 x 1.6 x 0.4 cm. The stapled edge measures 3.5 cm and

Status: complete

Page: 3 of 4

[page 4 of 4]
Department of Pathology

Patient Name:

MRN:

DOB:

Gender:

Service:

Visit #:

Location:

Facility:

Collected

Resulted:

Ordering MD:

is painted with India ink.

Pleural surface: Congested with surface adhesions.

Lung parenchyma: Brown and spongy

Masses or nodules: A firm tan ?nodule is identified measuring 1.1 x 0.6 x 0.5 cm and measures less than 0.1 cm from the painted stapled resection margin

Tissue Banking: No

Submitted in toto as follows:

2A shavings from stapled edge

2B- 2C ?nodule

2D remaining lung resection

3. The specimen is labeled with the patient's identification and as "Portion of Lingula".

Resection specimen: Wedge resection.

Measurements: 4.6 x 3.4 x 1.1 cm. the stapled edge measures 4.5 cm and is painted with India ink.

Pleural surface: Congested with focal areas of surface adhesion

Lung parenchyma: Brown and spongy with query an area of fibrosis

Masses or nodules: No

Tissue Banking: no

Submitted in toto as follows:

3A shaving from stapled edge

3B- 3E specimen serially sectioned

Status: complete

Source: NCI Genomic Data Commons file 7dd31197-8539-48ed-98d2-daa8aab0017f (TCGA-XU-A933.E5B9EE6F-7102-4771-8954-706431B70121.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).